Gene-level copy-number profile of tumor specimen BLGSP-71-06-00155-01B from CGCI case BLGSP-71-06-00155, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: female; Vital status: Alive; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS.
Specimen BLGSP-71-06-00155-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file cbe65535-ae94-42fc-ab94-7d84be92a914.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-06-00155-99A (granulocytes); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/b44cd457-a3da-41ce-8944-b92d005f351e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 705; copy number 2: 56,489; copy number 3: 1,168; copy number 4: 20; copy number 5: 4; copy number 9: 3; copy number 11: 1; copy number 32: 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:106,335,082–106,335,613, 1 gene (within-gene range 0–1): IGHV3-30.
- chr14:106,349,283–106,349,792, 1 gene (within-gene range 0–1): IGHV4-31.
- chr14:106,359,793–106,360,324, 1 gene (within-gene range 0–1): IGHV3-33.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,635,976–2,801,717, 3 genes, copy number 5 (within-gene range 2–5): TTC34, AC242022.2, AC242022.1.
- chr14:18,418,775–18,419,273, 1 gene, copy number 5: BNIP3P6.
- chr15:21,307,749–21,307,855, 1 gene, copy number 11: RNU6-1235P.
- chr15:21,980,277–21,981,245, 1 gene, copy number 9: OR11J6P.
- chr15:22,160,431–22,185,402, 3 genes, copy number 9–32: IGHV1OR15-1, IGHV1OR15-3, IGHV4OR15-8.

Autosomal genes at a single copy (total copy number 1): 705. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
